Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A2GM, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A2GM-06B (Metastatic).

DOB/Age/Sex:
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to:

HISTOPATHOLOGY REPORT

CLINICAL DETAILS

WEPC recurrent in transit metastasis left back. Histopath.

MACROSCOPIC DESCRIPTION

(Dr

"L BACK STITCH SUPERIOR". The specimen consists of an orientated ellipse of skin and subcutis measuring 65 x 30mm to the depth of 25mm. There is a marking stitch at superior designated as 12 o'clock. 12 o'clock half is inked blue and 6 o'clock half is inked black. On the skin surface, there is a linear scar measuring 30mm in length. The specimen is transversely sectioned from 3 o'clock to 9 o'clock. Sectioning of the specimen shows a tan brown nodule in subcutis with some involvement of epidermis measuring 15 x 13 x 10mm in maximum extent. The tumour lies about 8mm from 6 o'clock margin. The tumour also lies 15mm from deep margin.

A - B. Composite sections including the closest 12, 6 and deep margin

C. Further representative section of the lesion. Most of the lesion embedded. Tumour banking specimen taken.

MICROSCOPIC REPORT

Skin, left back

Location of tumour: dermis and subcutaneous tissue

Size of tumour: ~15 x 13 x 10mm (macroscopic)

Tumour description: nests and sheets of pleomorphic, mitotically active, focally pigmented epithelioid cells; tumour does not show an epidermal connection and a junctional melanocytic component is not identified, features in keeping with a metastatic/recurrent (rather than a primary) lesion

Distance to nearest peripheral margin: ~4.5mm (12 o'clock); ~7mm (6 o'clock)

Distance to deep margin: ~4.5mm

SUMMARY

Skin, left back

Melanoma.

REPORTED BY: Dr

1CD-0-3

Melanoma, NOS 8720/3

Site: Subcutaneous, back

C49.6

hw 6/10/11

Criteria	Previous revision seen @ site	Yes	No
Diagnosis Discrepancy	Melanoma site	✓	✗
Prior Malignancy History	Melanoma at other		✗

Source: NCI Genomic Data Commons file 11cb9e82-c540-463a-8803-9a81d31681ab (TCGA-EE-A2GM.D5563BB2-1989-4AEC-8013-098ED9C1DA08.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).